Gene-level copy-number profile of tumor specimen TCGA-D7-5578-01A from TCGA case TCGA-D7-5578, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 80.5 years (29,390 days).
Specimen TCGA-D7-5578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2fe3697b-1799-4a5f-81c7-1167e567a0ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-5578-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb83deda-86e0-4830-8f54-e5d34d6e49db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,476; copy number 2: 43,744; copy number 3: 529; copy number 4: 1,351; copy number 5: 1,007; copy number 6: 236; copy number 8: 328; copy number 9: 68; copy number 14: 81.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-5578-01A-01D-1599-01): tumor purity 0.6, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,720 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:167,648,430–170,814,548, 45 genes, copy number 6: PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1, HSP90AA6P, LINC02382, AC097486.1.
- chr8:8,783,354–12,818,291, 148 genes, copy number 9–14 (within-gene range 1–14) (broad region; genes not listed).
- chr8:12,958,387–12,962,200, 1 gene, copy number 9: AC135352.1.
- chr8:49,909,789–86,765,023, 551 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:93,754,844–96,611,790, 65 genes, copy number 6 (broad region; genes not listed).
- chr8:100,895,771–102,124,907, 32 genes, copy number 5 (within-gene range 4–5): RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2.
- chr8:109,777,912–111,236,203, 16 genes, copy number 5: AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37.
- chr8:113,600,310–145,066,685, 512 genes, copy number 5 (broad region; genes not listed).
- chr19:14,950,034–21,569,237, 350 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,055. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
